Somatic mutation profile of tumor specimen TCGA-E1-5319-01A (aliquot TCGA-E1-5319-01A-01D-1893-08) from TCGA case TCGA-E1-5319, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 48.2 years (17,612 days).
Specimen TCGA-E1-5319-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d12465ef-8b28-4298-8277-7db86fa16100.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-5319-10A (Blood Derived Normal), aliquot TCGA-E1-5319-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0bb3daf-d57b-4903-bdc9-3c5c6cd476d9

The open-access MAF lists 38 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 20, Silent 9, Frame Shift Del 6, In Frame Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 31/84 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- BTNL3 | c.326T>A p.I109N | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT tolerated (0.27); PolyPhen benign (0.068); catalogued as COSV61565885; called by muse, mutect2, varscan2
- CDH23 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs752103709, COSV54952692, COSV99818631, COSV99823209; called by muse, mutect2, varscan2
- CLN8 | c.752A>C p.H251P | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV58671495; called by muse, mutect2, varscan2
- COL4A5 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.062); catalogued as COSV100088057, COSV60372068; called by muse, mutect2, varscan2
- COQ5 | c.13G>T p.G5W | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV56019971, COSV56020486; called by muse, mutect2, varscan2
- FUBP1 | c.406A>G p.I136V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV53938536; called by muse, mutect2, varscan2
- MAGIX | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV66256617; called by muse, mutect2, varscan2
- MMP15 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); catalogued as rs147283654; called by muse, mutect2, varscan2
- MYH15 | c.2368G>C p.D790H | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV56319651; called by muse, mutect2
- SAGE1 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs868920111, COSV61012197; called by muse, mutect2, varscan2
- SI | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52266275, COSV52273498; called by muse, mutect2, varscan2
- SLC22A8 | c.926A>G p.K309R | Missense Mutation (SNP) | VAF 86/263 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.38); catalogued as COSV60327107; called by muse, mutect2, varscan2
- SSTR3 | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.162); catalogued as rs1354652511, COSV60730335; called by muse, mutect2, varscan2
- SYNE1 | c.418A>G p.S140G (on ENST00000367255 / NM_182961.4; = p.S147G on NM_033071.3) | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV55101226; called by muse, mutect2, varscan2
- SYNGAP1 | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53386653; called by muse, mutect2, varscan2
- TENM2 | c.6901C>T p.R2301C (on ENST00000518659 / NM_001122679.2; = p.R2062C on NM_001080428.3) | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as rs367824725, COSV69136412; called by muse, mutect2, varscan2
- UQCC2 | c.313A>G p.K105E | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV65268991; called by muse, mutect2, varscan2
- YTHDC1 | c.2048G>A p.R683Q (on ENST00000344157 / NM_001031732.4; = p.R665Q on NM_133370.4) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.457); catalogued as COSV60012066; called by muse, mutect2, varscan2
- CIC | c.3365_3366del p.V1122Gfs*28 | Frame Shift Del (DEL) | VAF 17/93 reads (18%) | called by pindel, varscan2
- HTR2A | c.638_639del p.F213Wfs*10 | Frame Shift Del (DEL) | VAF 19/96 reads (20%) | called by mutect2, pindel, varscan2
- KMT2C | c.13326_13327del p.Q4443Gfs*29 | Frame Shift Del (DEL) | VAF 32/209 reads (15%) | called by mutect2, pindel, varscan2
- LGALS13 | c.307_309del p.K103del | In Frame Del (DEL) | VAF 25/62 reads (40%) | called by mutect2, pindel, varscan2
- LRRC43 | c.1346del p.P449Qfs*33 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- MLLT3 | c.1343G>A p.S448N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); called by muse, varscan2
- NKX2-2 | c.258_259+4del p.X86_splice | Splice Site (DEL) | VAF 5/54 reads (9%) | called by mutect2, pindel, varscan2
- SYNJ2 | c.3032_3034del p.E1011del | In Frame Del (DEL) | VAF 28/162 reads (17%) | called by mutect2, pindel, varscan2
- TYK2 | c.221_222del p.F74Cfs*76 | Frame Shift Del (DEL) | VAF 42/158 reads (27%) | called by mutect2, pindel, varscan2
- UCK1 | c.325del p.T109Rfs*10 | Frame Shift Del (DEL) | VAF 41/156 reads (26%) | called by mutect2, pindel, varscan2
- ABCC12 | c.1356C>T p.T452= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV60918237; called by muse, mutect2, varscan2
- CD3D | c.141G>A p.T47= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs201021372, COSV52675199; called by muse, mutect2, varscan2
- DGKK | c.240A>G p.E80= | Silent (SNP) | VAF 23/465 reads (5%) | catalogued as COSV65709409; called by muse, mutect2
- JHY | c.444G>A p.P148= | Silent (SNP) | VAF 63/185 reads (34%) | catalogued as rs764739561, COSV56220911; called by muse, mutect2, varscan2
- LRIG3 | c.1875T>G p.A625= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV57869841; called by muse, mutect2, varscan2
- MARK1 | c.612T>C p.S204= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs771403262, COSV65071381; called by muse, mutect2, varscan2
- RBMX | c.903G>A p.P301= | Silent (SNP) | VAF 46/184 reads (25%) | catalogued as rs1474233366, COSV100284484, COSV104413318, COSV57809363; called by mutect2, varscan2
- RELT | c.312C>T p.P104= | Silent (SNP) | VAF 69/178 reads (39%) | catalogued as COSV50362869; called by muse, mutect2, varscan2
- STAU1 | c.1650A>G p.L550= (on ENST00000371856 / NM_001319135.1; = p.L469= on NM_004602.3) | Silent (SNP) | VAF 11/261 reads (4%) | catalogued as COSV61462601; called by muse, mutect2
